Somatic mutation profile of cancer-model specimen HCM-BROD-0416-C71-85B (3D Neurosphere, passage 14; aliquot HCM-BROD-0416-C71-85B-01D-A80U-36), derived from the primary tumor of HCMI case HCM-BROD-0416-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 73.1 years (26,690 days).
Specimen HCM-BROD-0416-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 14.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe3fbfe5-a0fa-4f13-a363-cbf59633c97d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0416-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0416-C71-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65c0dee9-f8cf-44fb-a4dc-5a4f17063985

The open-access MAF lists 125 somatic variants for this specimen: 76 protein-altering or splice-affecting, 43 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 43, Nonsense Mutation 4, Intron 3, Frame Shift Del 2, Frame Shift Ins 2, 3'UTR 2, Splice Site 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 187/189 reads (99%) | catalogued as rs371387815, CM110128, COSV64288370, COSV64295841; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC099489.1 | c.2488C>T p.R830* | Nonsense Mutation (SNP) | VAF 209/394 reads (53%) | catalogued as rs1213651772; called by muse, mutect2, varscan2
- ADAT3 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 285/932 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs982080035; called by muse, mutect2, varscan2
- AIRE | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 195/394 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs778067704, COSV52392624; called by muse, mutect2, varscan2
- AXDND1 | c.1693A>G p.S565G | Missense Mutation (SNP) | VAF 47/304 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as COSV62646362; called by muse, mutect2, varscan2
- BAZ2A | c.3507C>G p.F1169L | Missense Mutation (SNP) | VAF 4779/5266 reads (91%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV104385689; called by muse, mutect2, varscan2
- C8orf89 | c.457dup p.S153Kfs*24 | Frame Shift Ins (INS) | VAF 112/209 reads (54%) | catalogued as rs951061763; called by mutect2, varscan2
- CFAP299 | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 89/200 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs149721279; called by muse, mutect2, varscan2
- CHRNA9 | c.854T>G p.M285R | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100039109; called by muse, mutect2, varscan2
- COL13A1 | c.1916C>T p.A639V (on ENST00000398978 / NM_001130103.2; = p.A567V on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 386/386 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs561311848; called by muse, mutect2, varscan2
- CUX1 | c.2611C>T p.Q871* | Nonsense Mutation (SNP) | VAF 244/810 reads (30%) | catalogued as COSV99473389; called by muse, mutect2, varscan2
- DAW1 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 129/266 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100005737; called by muse, mutect2, varscan2
- DLEC1 | c.2830G>A p.V944I | Missense Mutation (SNP) | VAF 143/279 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs201448209; called by muse, mutect2, varscan2
- DNAH10 | c.5233G>A p.A1745T (on ENST00000409039; = p.A1684T on NM_207437.3) | Missense Mutation (SNP) | VAF 190/416 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as rs1345042500, COSV68996611; called by muse, varscan2
- DNAH8 | c.9505G>A p.D3169N | Missense Mutation (SNP) | VAF 81/163 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV100546826; called by muse, mutect2, varscan2
- EHD3 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 177/397 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.886); catalogued as rs201814896, COSV100434781, COSV59029271; called by muse, mutect2, varscan2
- GRIP1 | c.2881C>T p.R961W (on ENST00000359742 / NM_001379345.1; = p.R909W on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 234/508 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs761580569, COSV99669508; called by muse, mutect2, varscan2
- GRM7 | c.159del p.L54Cfs*46 | Frame Shift Del (DEL) | VAF 282/774 reads (36%) | catalogued as COSV63140513; called by pindel, varscan2
- HELZ2 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 262/880 reads (30%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1335466059, COSV64409892; called by muse, mutect2, varscan2
- IL31RA | c.1241C>A p.T414K | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.888); catalogued as rs1229853997; called by muse, mutect2, varscan2
- ITGA8 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 232/232 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150974250; called by muse, mutect2, varscan2
- KLK7 | c.127T>C p.W43R | Missense Mutation (SNP) | VAF 220/655 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780992617; called by muse, mutect2, varscan2
- LCE3E | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 311/687 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1398597048, COSV64232333; called by muse, mutect2, varscan2
- MYNN | c.179A>G p.N60S | Missense Mutation (SNP) | VAF 170/319 reads (53%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as rs773324179; called by muse, varscan2
- NECTIN2 | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 214/459 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs540886913; called by muse, mutect2, varscan2
- NKX1-2 | c.335C>A p.P112Q | Missense Mutation (SNP) | VAF 846/847 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV71184084; called by muse, mutect2, varscan2
- OPLAH | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 22/644 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782310069, COSV70678368; called by muse, mutect2
- PIP | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 127/376 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs750884957, COSV52120268; called by muse, mutect2, varscan2
- PNLIP | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 212/212 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs773774916, COSV65042392; called by muse, mutect2, varscan2
- PROX1 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 239/454 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs896925287, COSV54776196, COSV54779311; called by muse, mutect2, varscan2
- RP1L1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 127/279 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs886062587; called by muse, mutect2, varscan2
- SERPINA6 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 167/374 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as rs748984466; called by muse, mutect2, varscan2
- SHISA7 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 135/392 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); catalogued as rs941242224, COSV66244455; called by muse, mutect2, varscan2
- SLC4A1 | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 129/255 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as rs780297314, COSV52259143; called by muse, mutect2, varscan2
- TEAD1 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 173/392 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749486560, COSV57563458; called by muse, mutect2, varscan2
- UXS1 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 113/240 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774228502, COSV51676294; called by muse, mutect2, varscan2
- WIZ | c.4340G>A p.R1447Q (on ENST00000673675 / NM_001371589.1; = p.R352Q on NM_021241.3) | Missense Mutation (SNP) | VAF 160/474 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.107); catalogued as rs372083721, COSV54609315; called by muse, mutect2, varscan2
- ZNF398 | c.1565G>A p.R522H (on ENST00000475153 / NM_170686.3; = p.R351H on NM_020781.4) | Missense Mutation (SNP) | VAF 241/678 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs1013965037; called by muse, mutect2, varscan2
- ABCF2 | c.609G>C p.K203N | Missense Mutation (SNP) | VAF 177/603 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ADGRF5 | c.2630T>A p.L877H | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANTXR1 | c.1354-1G>A p.X452_splice | Splice Site (SNP) | VAF 87/163 reads (53%) | called by muse, mutect2, varscan2
- ARMC5 | c.715G>C p.V239L | Missense Mutation (SNP) | VAF 239/500 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ASB17 | c.753A>T p.K251N | Missense Mutation (SNP) | VAF 113/261 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CALCR | c.1202T>G p.F401C (on ENST00000649521 / NM_001164737.2; = p.F385C on NM_001742.4) | Missense Mutation (SNP) | VAF 16/563 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- CAPN10 | c.407G>C p.C136S | Missense Mutation (SNP) | VAF 167/391 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CBX7 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 60/331 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- COPS6 | c.929A>G p.N310S | Missense Mutation (SNP) | VAF 181/590 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- CRIM1 | c.3036T>A p.D1012E | Missense Mutation (SNP) | VAF 138/280 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CSF1R | c.389C>A p.T130K | Missense Mutation (SNP) | VAF 246/518 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNASE1L3 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 126/291 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EML6 | c.4808C>A p.T1603K | Missense Mutation (SNP) | VAF 172/393 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- FOXQ1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 247/500 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- G6PC2 | c.484A>C p.I162L | Missense Mutation (SNP) | VAF 109/272 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GOLGA8S | c.725C>A p.A242D | Missense Mutation (SNP) | VAF 17/406 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- KMT2B | c.3974G>T p.C1325F | Missense Mutation (SNP) | VAF 45/480 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MAML2 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 13/309 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2
- MAP1B | c.674G>C p.G225A | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MTM1 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 98/200 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2H2 | c.443T>A p.V148D | Missense Mutation (SNP) | VAF 21/697 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.295); called by muse, mutect2
- OR7E24 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 148/433 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- PKD1L1 | c.2420C>G p.S807C | Missense Mutation (SNP) | VAF 155/536 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNPLA4 | c.175dup p.I59Nfs*5 | Frame Shift Ins (INS) | VAF 101/265 reads (38%) | called by mutect2, pindel, varscan2
- POMGNT1 | c.577C>A p.L193M | Missense Mutation (SNP) | VAF 175/362 reads (48%) | PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- POTEE | c.360G>A p.W120* | Nonsense Mutation (SNP) | VAF 206/480 reads (43%) | called by muse, varscan2
- POU3F3 | c.1331A>G p.Q444R | Missense Mutation (SNP) | VAF 258/525 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- PTK7 | c.1027_1048del p.C343Qfs*66 | Frame Shift Del (DEL) | VAF 65/530 reads (12%) | called by mutect2, pindel
- SERPINB12 | c.754C>A p.L252I | Missense Mutation (SNP) | VAF 134/298 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SURF6 | c.751G>C p.D251H | Missense Mutation (SNP) | VAF 33/764 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- SYTL1 | c.1256C>A p.P419H (on ENST00000543823; = p.P407H on NM_032872.3) | Missense Mutation (SNP) | VAF 183/386 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- TGM6 | c.1213C>A p.H405N | Missense Mutation (SNP) | VAF 71/643 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNFRSF11A | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 249/520 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UGT2B10 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 106/197 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- VNN1 | c.1462G>T p.A488S | Missense Mutation (SNP) | VAF 16/398 reads (4%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.006); called by muse, mutect2
- WHRN | c.2422G>A p.G808R | Missense Mutation (SNP) | VAF 127/268 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WIZ | c.5117G>A p.S1706N (on ENST00000673675 / NM_001371589.1; = p.S611N on NM_021241.3) | Missense Mutation (SNP) | VAF 298/944 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ZNF512B | c.2551C>G p.R851G | Missense Mutation (SNP) | VAF 298/985 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ADD3 | c.1974C>T p.I658= (on ENST00000356080 / NM_001320591.2; = p.I626= on NM_001121.4) | Silent (SNP) | VAF 281/282 reads (100%) | catalogued as rs568629103; called by muse, mutect2, varscan2
- AHNAK2 | c.9339C>T p.V3113= | Silent (SNP) | VAF 300/517 reads (58%) | catalogued as rs747532273, COSV100319352; called by muse, varscan2
- AKR1C2 | c.690G>A p.P230= | Silent (SNP) | VAF 132/260 reads (51%) | called by muse, varscan2
- BMX | c.570T>A p.T190= | Silent (SNP) | VAF 231/444 reads (52%) | called by muse, mutect2, varscan2
- CACNA2D2 | c.1302C>T p.D434= | Silent (SNP) | VAF 346/512 reads (68%) | catalogued as rs587671504, COSV99818375; called by muse, mutect2, varscan2
- CACNG3 | c.339G>A p.T113= | Silent (SNP) | VAF 190/441 reads (43%) | catalogued as rs773149814, COSV50089370; called by muse, mutect2, varscan2
- CDH7 | c.1971C>T p.G657= | Silent (SNP) | VAF 100/236 reads (42%) | catalogued as rs772297804; called by muse, mutect2, varscan2
- COPZ2 | c.351C>T p.Y117= | Silent (SNP) | VAF 94/202 reads (47%) | catalogued as rs201805900; called by muse, mutect2, varscan2
- CR2 | c.1653G>A p.T551= | Silent (SNP) | VAF 182/381 reads (48%) | catalogued as rs373293174; called by muse, mutect2, varscan2
- CYP2E1 | c.111C>T p.F37= | Silent (SNP) | VAF 85/498 reads (17%) | catalogued as rs1428404245; called by muse, mutect2, varscan2
- DMXL2 | c.6639G>A p.A2213= | Silent (SNP) | VAF 134/289 reads (46%) | catalogued as rs185024518, COSV51845622; called by muse, mutect2, varscan2
- GRM7 | c.160C>T p.L54= | Silent (SNP) | VAF 317/728 reads (44%) | catalogued as rs1192256982, COSV63175571; called by muse, varscan2
- HTR3B | c.759C>T p.L253= | Silent (SNP) | VAF 156/322 reads (48%) | called by muse, mutect2, varscan2
- JPH2 | c.942C>T p.Y314= | Silent (SNP) | VAF 356/1054 reads (34%) | catalogued as rs1555858688, COSV100881790; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNH1 | c.513C>T p.S171= | Silent (SNP) | VAF 225/442 reads (51%) | catalogued as rs771777021; called by muse, mutect2, varscan2
- KCNH6 | c.2577C>T p.H859= | Silent (SNP) | VAF 236/494 reads (48%) | catalogued as rs547568764; called by muse, varscan2
- LCT | c.4761C>T p.R1587= | Silent (SNP) | VAF 186/407 reads (46%) | catalogued as rs573401319, COSV51545280, COSV51552658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LOXHD1 | c.3279C>T p.H1093= | Silent (SNP) | VAF 260/528 reads (49%) | catalogued as rs751278435; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NIBAN2 | c.1788C>T p.S596= | Silent (SNP) | VAF 232/477 reads (49%) | catalogued as rs1463545083; called by muse, mutect2, varscan2
- ODR4 | c.39G>A p.Q13= | Silent (SNP) | VAF 52/143 reads (36%) | called by muse, mutect2, varscan2
- OR5D13 | c.699A>T p.A233= | Silent (SNP) | VAF 239/448 reads (53%) | called by muse, mutect2, varscan2
- P2RY8 | c.888G>A p.A296= | Silent (SNP) | VAF 295/629 reads (47%) | catalogued as COSV67177132; called by muse, mutect2, varscan2
- PABPC5 | c.636C>T p.D212= | Silent (SNP) | VAF 212/423 reads (50%) | catalogued as rs1398599707; called by muse, mutect2, varscan2
- PCDHGA2 | c.1338C>T p.N446= | Silent (SNP) | VAF 255/475 reads (54%) | catalogued as COSV54040582; called by muse, mutect2, varscan2
- PCDHGA3 | c.1056C>T p.L352= | Silent (SNP) | VAF 198/413 reads (48%) | catalogued as rs780908329; called by muse, mutect2, varscan2
- PKD1L1 | c.2421C>T p.S807= | Silent (SNP) | VAF 155/531 reads (29%) | catalogued as rs753912551, COSV56958217; called by muse, mutect2, varscan2
- PKHD1 | c.9267C>A p.I3089= | Silent (SNP) | VAF 17/412 reads (4%) | called by muse, mutect2
- PLCD3 | c.81G>A p.A27= | Silent (SNP) | VAF 389/770 reads (51%) | called by muse, mutect2, varscan2
- PLEKHN1 | c.1122G>A p.P374= (on ENST00000379409; = p.P322= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 245/534 reads (46%) | catalogued as rs376185569; called by muse, mutect2, varscan2
- PPP1R2B | c.162G>A p.A54= | Silent (SNP) | VAF 147/350 reads (42%) | called by muse, mutect2, varscan2
- RC3H2 | c.3453A>G p.A1151= | Silent (SNP) | VAF 61/396 reads (15%) | called by muse, mutect2, varscan2
- RGL3 | c.690G>A p.A230= | Silent (SNP) | VAF 222/651 reads (34%) | called by muse, mutect2, varscan2
- RIPK4 | c.810G>A p.P270= | Silent (SNP) | VAF 266/501 reads (53%) | catalogued as rs914292273; called by muse, mutect2, varscan2
- SLC38A8 | c.417G>A p.P139= | Silent (SNP) | VAF 185/362 reads (51%) | catalogued as rs201796499; called by muse, mutect2, varscan2
- STK26 | c.21T>A p.A7= | Silent (SNP) | VAF 276/520 reads (53%) | called by muse, mutect2, varscan2
- SYTL1 | c.63G>A p.A21= | Silent (SNP) | VAF 190/398 reads (48%) | catalogued as rs1363074831; called by muse, mutect2, varscan2
- TBCK | c.2049C>T p.S683= (on ENST00000273980 / NM_001163436.4; = p.S620= on NM_033115.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/182 reads (13%) | catalogued as rs557016175, COSV99912136; called by muse, mutect2, varscan2
- TEAD2 | c.642G>A p.S214= | Silent (SNP) | VAF 181/389 reads (47%) | catalogued as rs758542961; called by muse, mutect2, varscan2
- TGIF2LX | c.177C>T p.A59= | Silent (SNP) | VAF 122/258 reads (47%) | catalogued as COSV99383299, COSV99383406; called by muse, mutect2, varscan2
- TINAG | c.39T>G p.L13= | Silent (SNP) | VAF 77/165 reads (47%) | catalogued as COSV52513253; called by muse, mutect2, varscan2
- ZAR1L | c.573C>T p.D191= | Silent (SNP) | VAF 275/276 reads (100%) | catalogued as rs750925355, COSV61526321; called by muse, mutect2, varscan2
- ZFHX4 | c.1068C>A p.P356= | Silent (SNP) | VAF 160/347 reads (46%) | catalogued as COSV50479574; called by muse, mutect2, varscan2
- ZIC4 | c.234C>T p.F78= | Silent (SNP) | VAF 284/566 reads (50%) | catalogued as rs748665259, COSV101268108; called by muse, varscan2
- DAPL1 | c.226-8793C>T | Intron (SNP) | VAF 131/211 reads (62%) | catalogued as rs769369042; called by muse, mutect2, varscan2
- DCHS2 | n.7604C>T | RNA (SNP) | VAF 139/304 reads (46%) | catalogued as rs748475572, COSV61769754; called by muse, mutect2, varscan2
- ELP1 | c.*346G>A | 3'UTR (SNP) | VAF 30/214 reads (14%) | called by muse, mutect2, varscan2
- GP6 | c.*191C>T | 3'UTR (SNP) | VAF 181/510 reads (35%) | called by muse, mutect2, varscan2
- KIF1A | c.2555+973G>A | Intron (SNP) | VAF 328/638 reads (51%) | catalogued as rs928176653; called by muse, varscan2
- OPRM1 | c.1165-10894G>A | Intron (SNP) | VAF 150/314 reads (48%) | catalogued as rs547145262, COSV57823877; called by muse, mutect2, varscan2
